Somatic mutation profile of tumor specimen TARGET-10-PAPHBW-09A (aliquot TARGET-10-PAPHBW-09A-01D) from TARGET case TARGET-10-PAPHBW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,362 days).
Specimen TARGET-10-PAPHBW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5eeae80-c655-4b2f-a2c5-a7a4908257e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHBW-14A (Bone Marrow Normal), aliquot TARGET-10-PAPHBW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09bbae18-a06e-4ba4-a313-f4d53d9f8b73

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGB1 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762664045, COSV61465794; called by muse, mutect2, varscan2
- LYG1 | c.179T>C p.I60T | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.372); catalogued as rs1227650350; called by muse, mutect2, varscan2
- NPAS2 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs761660915, COSV59560719; called by muse, mutect2, varscan2
- BCL11A | c.1378dup p.E460Gfs*78 (on ENST00000335712 / NM_001365609.1; = p.E494Gfs*78 on NM_018014.4) | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- ZNF189 | c.589A>T p.I197F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF551 | c.338T>C p.L113S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- RUSC2 | c.4104G>A p.S1368= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs796830914, COSV63427610; called by muse, mutect2, varscan2
- SLC35F4 | c.1008G>A p.A336= (on ENST00000339762 / NM_001352015.2; = p.A300= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs370452519, COSV100334105; called by muse, mutect2, varscan2
- AL691403.1 | n.225G>T | RNA (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
